Gene-level copy-number profile of tumor specimen TCGA-2Y-A9GY-01A from TCGA case TCGA-2Y-A9GY, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 64.2 years (23,435 days).
Specimen TCGA-2Y-A9GY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.039791fb-7dd8-4f3b-9a7f-c8b8368d9de1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2Y-A9GY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2cb4b3f4-2a58-4ea0-93aa-e80ada37ca43

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 824; copy number 2: 16,616; copy number 3: 28,357; copy number 4: 10,790; copy number 5: 2,426; copy number 6: 739; copy number 8: 3; copy number 10: 21; copy number 22: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2Y-A9GY-01A-11D-A381-01): tumor purity 0.52, ploidy 3.36, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 61 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:127,247,258–127,841,763, 21 genes, copy number 10: WBP11P2, ERCC3, AC068282.1, MAP3K2, RNU6-1147P, MAP3K2-DT, AC068282.2, PROC, MIR4783, IWS1, AC010976.1, RNU4-48P, MYO7B, AC010976.2, LIMS2, GPR17, WDR33, SFT2D3, RNY4P7, Y_RNA, ZFP91P1.
- chr9:32,293,558–32,454,769, 3 genes, copy number 8: RNA5SP281, SLC25A5P8, ACO1.
- chr19:28,683,071–30,085,893, 37 genes, copy number 22: AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.

Autosomal genes at a single copy (total copy number 1): 824. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
